Somatic mutation profile of tumor specimen HCM-BROD-0959-C18-06A (aliquot HCM-BROD-0959-C18-06A-01D-A881-36) from HCMI case HCM-BROD-0959-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: G4; Age at diagnosis: 66.3 years (24,234 days).
Specimen HCM-BROD-0959-C18-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24b2dae9-a79b-4a52-a0bd-8e5fd3a508ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0959-C18-10A (Blood Derived Normal), aliquot HCM-BROD-0959-C18-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af8c5cb8-baab-4843-a287-156b7cb8717e

The open-access MAF lists 129 somatic variants for this specimen: 94 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 34, Nonsense Mutation 8, In Frame Del 1, Splice Region 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CYLD | c.2299A>T p.K767* | Nonsense Mutation (SNP) | VAF 37/220 reads (17%) | catalogued as rs886040888, CM103649, COSV61098007; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 72/305 reads (24%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.914C>T p.A305V (on ENST00000614293; = p.A275V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/640 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1238610607; called by muse, mutect2, varscan2
- ABCB5 | c.3086A>G p.D1029G (on ENST00000404938 / NM_001163941.2; = p.D584G on NM_178559.6) | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1423293338; called by muse, mutect2, varscan2
- ACTL9 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs782182119, COSV61006158; called by muse, mutect2
- ADAMTS20 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs763907846; called by muse, mutect2, varscan2
- AMBRA1 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 85/320 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV54052815; called by muse, mutect2, varscan2
- AMOTL1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs773855698, COSV58569235; called by muse, mutect2, varscan2
- ANKRD36B | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51530181, COSV99307786; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs185758992; called by muse, mutect2, varscan2
- BEND7 | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 50/661 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61989897; called by muse, mutect2
- CDH12 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 40/517 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.116); catalogued as rs768928463, COSV66405593; called by muse, mutect2
- CEP112 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs147020220, COSV67137724; called by muse, mutect2, varscan2
- COL22A1 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.098); catalogued as rs537744559, COSV57330656; called by muse, mutect2, varscan2
- COL4A6 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 54/363 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170169985; called by muse, mutect2, varscan2
- COL6A1 | c.2693C>T p.T898M | Missense Mutation (SNP) | VAF 134/515 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs752473048; called by muse, mutect2, varscan2
- CPNE8 | c.1475G>C p.R492T | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.694); catalogued as COSV100504044, COSV58845078; called by muse, mutect2
- CYP4B1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as rs139750942; called by muse, mutect2, varscan2
- DHH | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 174/785 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1381598726; called by muse, mutect2, varscan2
- DHX33 | c.1769C>T p.T590M | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs745955062, COSV56579225; called by muse, mutect2
- FAM13A | c.2897G>T p.R966L | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52003043; called by muse, mutect2, varscan2
- FAM47B | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 67/423 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs898061216, COSV61452991; called by muse, mutect2, varscan2
- GREB1 | c.5149G>A p.V1717M | Missense Mutation (SNP) | VAF 60/455 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs377649994; called by muse, mutect2, varscan2
- GUCY1A2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 130/595 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1414562428; called by mutect2, varscan2
- H1-5 | c.615_629del p.P213_K217del | In Frame Del (DEL) | VAF 41/373 reads (11%) | catalogued as rs758100284; called by mutect2, varscan2
- ITIH5 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 70/407 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56901066; called by muse, mutect2, varscan2
- JAKMIP1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 134/762 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV99288898; called by muse, mutect2, varscan2
- LEMD1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs772245225; called by muse, mutect2, varscan2
- MARCO | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 50/419 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.459); catalogued as rs773925484, COSV100503279, COSV59051612; called by muse, mutect2, varscan2
- MIGA2 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 107/461 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs549699802, COSV52978461; called by muse, varscan2
- MYH14 | c.4096C>T p.R1366C | Missense Mutation (SNP) | VAF 63/526 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs535145284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCKAP5L | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 143/723 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371319353; called by muse, mutect2, varscan2
- NEB | c.7316C>T p.S2439L | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs774282909; called by muse, mutect2, varscan2
- NMUR1 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 107/734 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763514103, COSV59405556; called by muse, mutect2, varscan2
- NTM | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs763290433, COSV66204184; called by muse, mutect2, varscan2
- OR4K13 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150686832, COSV100237803, COSV59859719; called by muse, mutect2, varscan2
- OSBPL3 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 93/530 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs749326073, COSV57655492; called by muse, mutect2, varscan2
- PGA5 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 77/354 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as rs200807597; called by muse, mutect2, varscan2
- POSTN | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 38/598 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs775213102, COSV65712393; called by muse, mutect2
- RGS6 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 81/547 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs751525654, COSV100664715, COSV59579508; called by muse, mutect2, varscan2
- RHEX | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 35/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs531574406, COSV58980514; called by muse, mutect2
- SARDH | c.2623G>A p.G875S | Missense Mutation (SNP) | VAF 87/376 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs760438211, COSV64100968; called by muse, mutect2, varscan2
- SEMA3F | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 115/437 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756328900, COSV50029351; called by muse, mutect2, varscan2
- SLITRK5 | c.2716G>T p.A906S | Missense Mutation (SNP) | VAF 155/648 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as COSV61522620; called by muse, mutect2, varscan2
- SMTNL1 | c.908G>A p.R303Q (on ENST00000399154; = p.R340Q on NM_001105565.2) | Missense Mutation (SNP) | VAF 128/511 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs372952972; called by muse, mutect2, varscan2
- SPRED3 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 76/440 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs779195105; called by mutect2, varscan2
- STS | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs372945330; called by muse, mutect2, varscan2
- TENM3 | c.7763G>A p.G2588D | Missense Mutation (SNP) | VAF 98/454 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV101305251; called by muse, mutect2, varscan2
- TMC7 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs150991752, COSV99076143; called by muse, mutect2, varscan2
- UGT1A7 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 90/371 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1559339683; called by muse, mutect2, varscan2
- WDR90 | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.369); catalogued as COSV53469133; called by muse, mutect2, varscan2
- WFS1 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 96/966 reads (10%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs372783392; ClinVar: likely benign; called by muse, mutect2
- AAR2 | c.756del p.G253Vfs*26 | Frame Shift Del (DEL) | VAF 34/287 reads (12%) | called by mutect2, pindel, varscan2
- ATM | c.3662G>A p.W1221* | Nonsense Mutation (SNP) | VAF 38/233 reads (16%) | called by muse, mutect2, varscan2
- ATP1A1 | c.1236C>G p.D412E | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CCER2 | c.301A>G p.R101G | Missense Mutation (SNP) | VAF 23/545 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2
- CDK15 | c.1083A>C p.E361D (on ENST00000652192 / NM_001366386.2; = p.E310D on NM_139158.2) | Missense Mutation (SNP) | VAF 33/398 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.565); called by muse, mutect2
- CHAMP1 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 42/732 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- COG6 | c.297G>A p.E99= | Splice Region (SNP) | VAF 19/331 reads (6%) | called by muse, mutect2
- COL12A1 | c.4367C>T p.S1456F | Missense Mutation (SNP) | VAF 128/353 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EML4 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 74/286 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ERICH2 | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM135B | c.1328A>G p.D443G | Missense Mutation (SNP) | VAF 146/388 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM171B | c.1486C>T p.H496Y | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- GRM4 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, varscan2
- GTSE1 | c.1819G>T p.A607S | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2
- HAUS2 | c.121G>T p.V41F | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.173); called by mutect2, varscan2
- HJV | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 132/679 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- IGF2R | c.4663G>T p.E1555* | Nonsense Mutation (SNP) | VAF 14/446 reads (3%) | called by muse, mutect2
- JSRP1 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 72/541 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- KLHL29 | c.2359T>G p.Y787D | Missense Mutation (SNP) | VAF 91/480 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); called by muse, mutect2
- LDLRAD4 | c.729C>A p.S243R | Missense Mutation (SNP) | VAF 72/864 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- MEPCE | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 102/701 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.10987T>A p.L3663M | Missense Mutation (SNP) | VAF 21/374 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- NOL4L | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NTN5 | c.574T>A p.S192T | Missense Mutation (SNP) | VAF 78/577 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PHF14 | c.1678G>T p.V560F | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- PTAR1 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 94/387 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRK | c.2879G>T p.G960V (on ENST00000368215 / NM_001291984.2; = p.G961V on NM_002844.4) | Missense Mutation (SNP) | VAF 116/284 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REX1BD | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 123/652 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RRAGB | c.613C>T p.R205* (on ENST00000262850 / NM_016656.4; = p.R177* on NM_006064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/286 reads (9%) | called by muse, mutect2
- SEMA3E | c.1586G>T p.C529F | Missense Mutation (SNP) | VAF 30/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC39A7 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 84/665 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SMG5 | c.909C>G p.S303R | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.089); called by muse, mutect2
- TAF1L | c.4492G>T p.E1498* | Nonsense Mutation (SNP) | VAF 26/435 reads (6%) | called by muse, mutect2
- TMEM266 | c.1355G>T p.C452F | Missense Mutation (SNP) | VAF 72/626 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TMPRSS9 | c.2996G>A p.R999Q (on ENST00000648592; = p.R965Q on NM_182973.2) | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.288); called by muse, mutect2
- TPR | c.4478T>G p.L1493R | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- UHMK1 | c.719A>G p.K240R | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- UVSSA | c.754T>G p.C252G | Missense Mutation (SNP) | VAF 169/753 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDFY3 | c.8095G>A p.E2699K | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ZNF189 | c.992T>G p.L331R | Missense Mutation (SNP) | VAF 32/565 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZSCAN31 | c.1152C>A p.C384* | Nonsense Mutation (SNP) | VAF 22/308 reads (7%) | called by muse, mutect2
- AMPD3 | c.2112C>T p.S704= (on ENST00000396553 / NM_001025389.2; = p.S713= on NM_000480.3) | Silent (SNP) | VAF 22/381 reads (6%) | catalogued as rs752630433, COSV67332332; called by muse, mutect2
- C22orf23 | c.237C>T p.A79= | Silent (SNP) | VAF 75/302 reads (25%) | called by muse, mutect2, varscan2
- CCN6 | c.480G>T p.L160= | Silent (SNP) | VAF 30/518 reads (6%) | called by muse, mutect2
- CD1D | c.999C>T p.G333= | Silent (SNP) | VAF 76/363 reads (21%) | catalogued as rs1473349997, COSV63809340; called by muse, mutect2, varscan2
- CDKL5 | c.615C>T p.S205= | Silent (SNP) | VAF 54/340 reads (16%) | catalogued as rs1273092102; called by muse, mutect2, varscan2
- CLRN2 | c.381G>A p.P127= | Silent (SNP) | VAF 88/502 reads (18%) | catalogued as rs374029760; called by muse, mutect2, varscan2
- CNTN1 | c.360C>T p.Y120= | Silent (SNP) | VAF 45/316 reads (14%) | catalogued as rs572299257, COSV61638568; called by muse, mutect2, varscan2
- COL22A1 | c.576C>T p.P192= | Silent (SNP) | VAF 200/595 reads (34%) | called by muse, mutect2, varscan2
- COL2A1 | c.1353G>A p.P451= | Silent (SNP) | VAF 91/333 reads (27%) | catalogued as rs560149744, COSV61535859; called by muse, mutect2, varscan2
- COL5A1 | c.3897C>T p.G1299= | Silent (SNP) | VAF 107/520 reads (21%) | catalogued as rs745918663; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DGKH | c.981G>A p.S327= | Silent (SNP) | VAF 96/344 reads (28%) | catalogued as rs753953792, COSV54930103; called by muse, mutect2, varscan2
- DTNB | c.1116C>T p.A372= | Silent (SNP) | VAF 61/282 reads (22%) | catalogued as rs755885793; called by muse, mutect2, varscan2
- DYNC1LI2 | c.885C>T p.H295= | Silent (SNP) | VAF 37/476 reads (8%) | called by muse, mutect2
- GOLGA8H | c.360A>C p.A120= | Silent (SNP) | VAF 60/427 reads (14%) | called by muse, mutect2, varscan2
- HOXB3 | c.759C>A p.A253= | Silent (SNP) | VAF 76/495 reads (15%) | called by muse, mutect2, varscan2
- IRAK3 | c.1284G>A p.T428= | Silent (SNP) | VAF 139/345 reads (40%) | catalogued as rs373101549; called by muse, mutect2, varscan2
- KCNH1 | c.1221C>T p.D407= (on ENST00000271751 / NM_172362.3; = p.D380= on NM_002238.4) | Silent (SNP) | VAF 75/427 reads (18%) | catalogued as rs138866428; called by muse, mutect2, varscan2
- KLK2 | c.660T>C p.N220= | Silent (SNP) | VAF 47/279 reads (17%) | called by muse, mutect2, varscan2
- LCN6 | c.213G>A p.T71= | Silent (SNP) | VAF 67/370 reads (18%) | catalogued as rs776445939; called by muse, varscan2
- MMP16 | c.1162T>C p.L388= | Silent (SNP) | VAF 52/562 reads (9%) | catalogued as COSV54175920, COSV54189671, COSV99691040; called by muse, mutect2
- MUC12 | c.11886C>A p.T3962= (on ENST00000379442; = p.T3819= on NM_001164462.1) | Silent (SNP) | VAF 178/380 reads (47%) | called by mutect2, varscan2
- OR4K15 | c.855C>T p.P285= (on ENST00000305051; = p.P261= on NM_001005486.1) | Silent (SNP) | VAF 39/531 reads (7%) | called by muse, mutect2
- OR6N1 | c.931T>C p.L311= | Silent (SNP) | VAF 17/177 reads (10%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.2019G>A p.A673= | Silent (SNP) | VAF 128/525 reads (24%) | catalogued as rs776657082; called by muse, mutect2, varscan2
- PMCH | c.474C>G p.V158= | Silent (SNP) | VAF 41/289 reads (14%) | catalogued as rs759732671; called by muse, mutect2, varscan2
- PPIAL4G | c.468C>A p.I156= | Silent (SNP) | VAF 18/177 reads (10%) | catalogued as rs1273938457; called by muse, mutect2, varscan2
- RBMXL2 | c.906C>T p.Y302= | Silent (SNP) | VAF 90/392 reads (23%) | catalogued as rs774916563, COSV100182057; called by muse, varscan2
- SPIDR | c.2631A>C p.G877= | Silent (SNP) | VAF 109/397 reads (27%) | called by muse, mutect2, varscan2
- SVEP1 | c.7590C>T p.L2530= | Silent (SNP) | VAF 107/521 reads (21%) | catalogued as rs369617735; called by muse, mutect2, varscan2
- THSD4 | c.516C>A p.A172= | Silent (SNP) | VAF 23/405 reads (6%) | called by muse, mutect2
- TRIM50 | c.531C>T p.R177= | Silent (SNP) | VAF 96/548 reads (18%) | catalogued as rs1194371507; called by muse, mutect2, varscan2
- VPS51 | c.1362G>C p.L454= | Silent (SNP) | VAF 61/387 reads (16%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.78C>T p.L26= | Silent (SNP) | VAF 134/541 reads (25%) | catalogued as rs751582921; called by muse, varscan2
- ZFHX4 | c.1668C>A p.G556= | Silent (SNP) | VAF 107/377 reads (28%) | catalogued as rs1438067671; called by muse, mutect2, varscan2
- TREX2 | c.-290G>C | 5'UTR (SNP) | VAF 76/484 reads (16%) | called by muse, mutect2, varscan2
